Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7471, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7471-01A (Primary Tumor).

Addendum Discussion:

The calculated MIB-1 Labeling Index is 19.2% consistent with a high grade glioma.

Addendum Diagnosis:

Anaplastic Oligodendroglioma (Who grade III)

MIB-1 Labeling Index= 19.2%

Microscopic Description:

Microscopic examination reveals a moderately cellular infiltrating glioma. The tumor cells demonstrate moderate to marked nuclear atypia, including neoplastic cells with enlarged hyperchromatic nuclei. The tumor cells demonstrate prominent perinuclear halos consistent with oligodendroglial differentiation. They diffusely infiltrate the adjacent brain parenchyma. Focal areas of microcystic change are seen. Neither necrosis nor microvascular proliferation are identified. Only a rare mitotic figure at less than one per ten high power fields is seen. Although the neoplasm lacks significant mitotic activity, the hypercellularity and nuclear atypia are worrisome for a high grade tumor. Overall, the histological features are consistent with an oligodendroglioma. A final diagnosis will be issued pending review of MIB-1 Labeling Index.

Source: NCI Genomic Data Commons file e619d86a-b2f1-4751-b3fe-013a82dcf8b1 (TCGA-HT-7471.424D1EA1-6333-45BB-B04E-027B47E6581E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).